MP2PRT case MP2PRT-PAUMFA — Molecular Profiling to Predict Response to Treatment - Wilms Tumor (MP2PRT-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Kidney. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/a4aa7d6f-7f02-4d6c-be97-1ccdf2c12d67

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2002; Vital status: Dead; Days to death: 999 days (2.7 years); Year of death: 2014.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 9.7 years (3,554 days); Wilms tumor histologic subtype: Favorable.
   Treatment — whether it was given is not recorded by GDC; Regimen or line of therapy: DD-4A.

Biospecimens (3 samples)
- Sample MP2PRT-PAUMFA-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
- Sample MP2PRT-PAUMFA-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
- Sample MP2PRT-PAUMFA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
